Somatic mutation profile of tumor specimen C3L-01249-01 (aliquot CPT0080880009) from CPTAC case C3L-01249, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 65.2 years (23,797 days).
Specimen C3L-01249-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1cb0745-ac41-45e9-9bab-a7b5f72e86e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01249-71 (Blood Derived Normal), aliquot CPT0080920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/013e3d9d-872d-4277-914e-1fd8e79ce921

The open-access MAF lists 47 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Intron 4, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 162/882 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CREBBP | c.4230dup p.G1411Wfs*10 | Frame Shift Ins (INS) | VAF 108/582 reads (19%) | catalogued as rs1555473668; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 55/336 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACCSL | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs775097461, COSV66581652; called by muse, mutect2
- CFAP74 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs887385307; called by muse, mutect2, varscan2
- CHST2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs761599439; called by muse, mutect2, varscan2
- EFR3B | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.143); catalogued as rs373458540; called by muse, mutect2, varscan2
- H2BC14 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1156861155, COSV60798368; called by muse, mutect2, varscan2
- ITIH6 | c.2428C>A p.P810T | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1162150101; called by muse, mutect2, varscan2
- KLK3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs148892721; called by muse, varscan2
- KNDC1 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177916154, COSV58844070; called by muse, mutect2, varscan2
- MAP3K13 | c.1529A>G p.K510R | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as rs760908174; called by muse, mutect2, varscan2
- NALCN | c.4466G>A p.R1489H | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs149644813; called by muse, mutect2, varscan2
- RASSF1 | c.1004A>G p.Q335R (on ENST00000357043 / NM_170714.2; = p.Q331R on NM_007182.5) | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs781828303; called by muse, mutect2, varscan2
- TCF20 | c.3397C>T p.R1133W | Missense Mutation (SNP) | VAF 68/482 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.993); catalogued as rs756751149, COSV100166397; called by muse, mutect2, varscan2
- ANKRD33B | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- COG1 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 136/810 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DIAPH2 | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2
- FAM50A | c.648+8G>A | Splice Region (SNP) | VAF 32/156 reads (21%) | called by muse, mutect2, varscan2
- GLYR1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- MYH1 | c.5187C>A p.N1729K | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- NME8 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NOP9 | c.794_801del p.L265Hfs*7 | Frame Shift Del (DEL) | VAF 66/385 reads (17%) | called by mutect2, pindel, varscan2
- OR1M1 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 80/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR3F | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- PTEN | c.150_151del p.D51* | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- SETDB1 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPAST | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- STK38 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX13C | c.1647A>T p.K549N | Missense Mutation (SNP) | VAF 149/921 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TFDP1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- VCPIP1 | c.3052C>A p.Q1018K | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CACNA1B | c.501C>T p.N167= | Silent (SNP) | VAF 50/301 reads (17%) | catalogued as rs4422842; called by muse, mutect2, varscan2
- DSP | c.1590C>T p.Y530= | Silent (SNP) | VAF 87/543 reads (16%) | catalogued as rs769196176, COSV65796631; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM171B | c.2382C>T p.S794= | Silent (SNP) | VAF 44/276 reads (16%) | called by muse, mutect2, varscan2
- KCND3 | c.1866G>A p.A622= | Silent (SNP) | VAF 137/786 reads (17%) | catalogued as rs766650482; called by muse, mutect2, varscan2
- LRRC18 | c.306C>T p.N102= | Silent (SNP) | VAF 56/331 reads (17%) | catalogued as rs747681722, COSV53283330; called by muse, mutect2, varscan2
- LZTS1 | c.27C>T p.S9= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs773405615, COSV56118069; called by muse, mutect2
- MAP7D3 | c.2253C>T p.S751= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs963140818, COSV60173178; called by muse, mutect2, varscan2
- NIPA2 | c.516C>T p.R172= | Silent (SNP) | VAF 61/307 reads (20%) | called by muse, mutect2, varscan2
- NOTCH1 | c.2295C>T p.G765= | Silent (SNP) | VAF 133/668 reads (20%) | catalogued as rs144066379; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM26 | c.2679G>A p.L893= (on ENST00000438737 / NM_001366735.2; = p.L866= on NM_022118.5) | Silent (SNP) | VAF 127/617 reads (21%) | called by muse, mutect2, varscan2
- ZNF469 | c.6171G>A p.E2057= (on ENST00000437464; = p.E2085= on NM_001367624.2) | Silent (SNP) | VAF 35/189 reads (19%) | catalogued as rs1296847847; called by muse, mutect2, varscan2
- DPP6 | c.627+20892G>A | Intron (SNP) | VAF 133/604 reads (22%) | catalogued as rs367792888; called by muse, mutect2, varscan2
- EIF4A2 | c.909+97_909+101del | Intron (DEL) | VAF 40/211 reads (19%) | catalogued as rs1264440511; called by mutect2, pindel, varscan2
- MTFR1L | c.25-232C>T | Intron (SNP) | VAF 55/317 reads (17%) | catalogued as rs1252306847; called by muse, mutect2, varscan2
- STARD3 | c.429+95C>G | Intron (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
